Somatic mutation profile of tumor specimen TCGA-FD-A6TG-01A (aliquot TCGA-FD-A6TG-01A-11D-A32B-08) from TCGA case TCGA-FD-A6TG, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 73.6 years (26,893 days).
Specimen TCGA-FD-A6TG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1872c9b5-de45-4453-8134-52a76844ab9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A6TG-10A (Blood Derived Normal), aliquot TCGA-FD-A6TG-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be096509-0bae-445a-9749-cbbe146e0a66

The open-access MAF lists 397 somatic variants for this specimen: 296 protein-altering or splice-affecting, 92 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 266, Silent 92, Nonsense Mutation 22, Intron 5, Frame Shift Del 4, Splice Site 3, 3'UTR 2, Splice Region 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2
- HEXA | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs121907953, CM900126, COSV51507647; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KAT8 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 16/71 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54896480; called by muse, mutect2, varscan2
- ABCB5 | c.2458G>A p.A820T (on ENST00000404938 / NM_001163941.2; = p.A375T on NM_178559.6) | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs747525237, COSV51720822; called by muse, mutect2
- ABCC2 | c.3520C>T p.R1174C | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746497342, COSV64987502; called by muse, mutect2, varscan2
- ABCC4 | c.3594G>C p.L1198F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65318336; called by muse, mutect2
- ABCG4 | c.1520C>G p.S507* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100267057; called by muse, mutect2, varscan2
- ACAN | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61369449; called by muse, mutect2, varscan2
- ACBD3 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as rs1390781438, COSV64731277; called by muse, mutect2
- ACOT2 | c.784A>G p.M262V | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1432541200, COSV53151579; called by muse, mutect2, varscan2
- ADAM10 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.612); catalogued as COSV53053820, COSV53054844; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2852C>T p.P951L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV65900295; called by muse, mutect2, varscan2
- ADAP1 | c.894C>A p.F298L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV56217418; called by muse, mutect2, varscan2
- AHNAK2 | c.10011G>C p.K3337N | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); catalogued as COSV60930602; called by muse, mutect2, varscan2
- AJUBA | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV52984625, COSV99401209; called by muse, mutect2, varscan2
- AL592490.1 | c.1880T>A p.L627H | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV69427873; called by muse, mutect2, varscan2
- ANKDD1A | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs553148491, COSV60353072; called by mutect2, varscan2
- ANKRD11 | c.4042G>T p.E1348* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | catalogued as COSV99970680; called by muse, mutect2, varscan2
- ANO10 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.292); catalogued as COSV99429084; called by muse, mutect2
- AOC2 | c.103C>G p.P35A | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV53200347; called by muse, mutect2, varscan2
- APMAP | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV54172354, COSV54177028; called by muse, mutect2
- APOB | c.6973A>T p.I2325F | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV51952357; called by muse, mutect2, varscan2
- APOBEC4 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV58017545; called by muse, mutect2, varscan2
- AQP6 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59646687; called by muse, mutect2
- ARID1A | c.3178G>T p.E1060* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100253584; called by muse, mutect2, varscan2
- ATAD5 | c.4063A>T p.S1355C | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs150095617; called by muse, mutect2
- ATN1 | c.1946A>G p.Y649C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.907); catalogued as rs781963846, COSV100755963; called by muse, mutect2
- ATN1 | c.3040G>C p.D1014H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.981); catalogued as rs1156427953, COSV63111961; called by muse, mutect2, varscan2
- ATP6V0A1 | c.2425G>C p.E809Q (on ENST00000343619 / NM_001378531.1; = p.E803Q on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/282 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52877890; called by muse, mutect2
- BLM | c.3772G>A p.E1258K | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV61927418; called by muse, mutect2
- BMP10 | c.1201T>C p.Y401H | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54897195; called by muse, mutect2, varscan2
- BPIFA3 | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64926256, COSV64926316; called by muse, mutect2
- BRIP1 | c.3470G>C p.R1157T | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.02); catalogued as rs776599258, COSV52008882; called by muse, mutect2, varscan2
- C2CD3 | c.3065C>A p.T1022K | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58100959; called by muse, mutect2, varscan2
- C9 | c.1237G>T p.A413S | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV54681619; called by muse, mutect2, varscan2
- CAB39L | c.398A>G p.Y133C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1158255504, COSV61716877; called by muse, mutect2, varscan2
- CALD1 | c.1220A>G p.E407G | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV62654091; called by muse, mutect2, varscan2
- CAMSAP2 | c.3709A>G p.M1237V (on ENST00000236925 / NM_001297707.2; = p.M1226V on NM_203459.3) | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV52677305; called by muse, mutect2, varscan2
- CARD10 | c.1798A>G p.I600V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52660113; called by muse, mutect2
- CASP1 | c.171G>C p.L57F | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.558); catalogued as COSV100782856; called by muse, mutect2
- CCDC171 | c.2681C>G p.S894C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as COSV52653125, COSV52653404; called by muse, mutect2, varscan2
- CD1B | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 27/285 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs752275251, COSV63804991; called by muse, mutect2
- CDCA7L | c.1250A>G p.K417R | Missense Mutation (SNP) | VAF 65/94 reads (69%) | SIFT tolerated (0.89); PolyPhen benign (0.024); catalogued as COSV60981388; called by muse, mutect2, varscan2
- CDH13 | c.2052T>A p.N684K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51868789; called by muse, mutect2, varscan2
- CDK5 | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV52525841; called by muse, mutect2
- CERKL | c.1534G>A p.E512K (on ENST00000339098 / NM_001030311.2; = p.E486K on NM_201548.5) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.026); catalogued as COSV59213669; called by muse, mutect2, varscan2
- CHD5 | c.4843G>A p.E1615K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1318984020, COSV52424832; called by muse, mutect2, varscan2
- CHRNA2 | c.1031T>C p.V344A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as COSV53559809; called by muse, mutect2
- CLIP1 | c.4066G>A p.G1356R (on ENST00000620786 / NM_001247997.1; = p.G1345R on NM_002956.2) | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs201297279; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLSPN | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV52057117; called by muse, mutect2, varscan2
- CNBD2 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); catalogued as COSV62588003; called by muse, mutect2, varscan2
- CNNM1 | c.1319T>C p.F440S | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV63203427; called by muse, mutect2, varscan2
- CNNM4 | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV65662129; called by muse, mutect2
- CNTNAP4 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as rs1014910351, COSV56669618; called by muse, mutect2, varscan2
- COL12A1 | c.2320C>T p.Q774* | Nonsense Mutation (SNP) | VAF 31/230 reads (13%) | catalogued as COSV100486587; called by muse, mutect2, varscan2
- COL4A2 | c.4358G>A p.G1453E | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV64634165; called by muse, mutect2
- CORIN | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs546767397, COSV56699395; called by muse, mutect2, varscan2
- CPEB1 | c.446T>C p.L149P (on ENST00000617958; = p.L89P on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.022); catalogued as COSV55621573; called by muse, mutect2
- CPT2 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1306249124, COSV53760383; called by muse, mutect2, varscan2
- CPVL | c.571C>G p.P191A | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as COSV55304700, COSV55308607; called by muse, mutect2, varscan2
- CSTF2 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV65895181; called by muse, mutect2, varscan2
- CYLC1 | c.980A>G p.K327R | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.82); catalogued as COSV100255541; called by muse, mutect2, varscan2
- DAGLB | c.1656G>T p.Q552H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV51706902; called by muse, mutect2, varscan2
- DHRS9 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59141733; called by muse, mutect2, varscan2
- DHX38 | c.2370C>G p.I790M | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200450334, COSV51700970; called by muse, mutect2, varscan2
- DIDO1 | c.4225G>A p.E1409K | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as rs770549757, COSV56623373, COSV56627673; called by muse, mutect2
- DMBX1 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs373771353, COSV63602618; called by muse, mutect2, varscan2
- DMD | c.5627C>T p.S1876F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV63767582, COSV63791573; called by muse, mutect2
- DMXL2 | c.5215G>C p.E1739Q | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51856198; called by muse, mutect2, varscan2
- DNAH11 | c.10981G>A p.E3661K | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.043); catalogued as COSV60981362; called by muse, mutect2
- DNAH5 | c.2291C>G p.S764* | Nonsense Mutation (SNP) | VAF 12/121 reads (10%) | catalogued as CM1414802, COSV99454489; called by muse, mutect2
- DNAH7 | c.5845A>G p.I1949V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as rs1430821409, COSV56786419; called by muse, mutect2, varscan2
- DPEP3 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV52052535; called by muse, mutect2, varscan2
- DSP | c.5866G>C p.E1956Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV101131798; called by muse, mutect2
- DUOXA1 | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as COSV50994901; called by muse, mutect2, varscan2
- DUSP22 | c.284G>A p.S95N | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1289543199, COSV60531462; called by muse, mutect2
- DVL2 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV50039767; called by muse, mutect2, varscan2
- EIF4G1 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV59993835; called by muse, mutect2, varscan2
- EIF4G1 | c.1117G>C p.E373Q (on ENST00000346169 / NM_198241.3; = p.E177Q on NM_004953.5) | Missense Mutation (SNP) | VAF 75/197 reads (38%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.954); catalogued as COSV59989142, COSV59989818; called by muse, mutect2, varscan2
- EIF4G1 | c.1755G>C p.E585D (on ENST00000346169 / NM_198241.3; = p.E389D on NM_004953.5) | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as COSV59993843; called by muse, mutect2, varscan2
- ELAVL4 | c.890G>C p.W297S | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV63919131; called by muse, mutect2, varscan2
- EP300 | c.3244C>T p.Q1082* | Nonsense Mutation (SNP) | VAF 72/237 reads (30%) | catalogued as COSV54332154; called by muse, mutect2, varscan2
- EPC1 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV53929799, COSV53929975; called by muse, mutect2, varscan2
- EPHA5 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.076); catalogued as rs773032839, COSV56634701; called by mutect2, varscan2
- ERAL1 | c.694G>T p.V232F | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV54740995; called by muse, mutect2, varscan2
- ERC1 | c.2157G>A p.K719= (on ENST00000360905 / NM_178040.4; = p.K691= on NM_178039.4) | Splice Region (SNP) | VAF 8/31 reads (26%) | catalogued as COSV61699573; called by muse, mutect2, varscan2
- ESPL1 | c.1618G>T p.E540* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99229807; called by muse, mutect2, varscan2
- FAT2 | c.2116C>G p.Q706E | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.91); PolyPhen benign (0.053); catalogued as COSV55829375; called by muse, mutect2, varscan2
- FGG | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.299); catalogued as COSV60195366, COSV60196193; called by muse, mutect2, varscan2
- G6PC3 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV52243864; called by muse, mutect2, varscan2
- GABRB3 | c.773C>A p.T258K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100161964, COSV54652552, COSV54658230; called by mutect2, varscan2
- GCOM1 | c.571C>G p.Q191E | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.219); catalogued as COSV51098208; called by muse, mutect2
- GDI2 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100051102; called by muse, mutect2
- GDI2 | c.108C>G p.N36K | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV66336136; called by muse, mutect2
- GDPD4 | c.1384T>C p.F462L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV60023045; called by muse, mutect2, varscan2
- GMPR | c.807G>T p.M269I | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99440596; called by muse, mutect2
- GNL3L | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60577667; called by muse, mutect2, varscan2
- GOLGA3 | c.1784A>T p.E595V | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52643325; called by muse, mutect2, varscan2
- GPHB5 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58487166; called by mutect2, varscan2
- GPR179 | c.2126G>A p.R709Q (on ENST00000621958; = p.R708Q on NM_001004334.4) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as rs376095793; called by muse, mutect2
- GRIN2D | c.1123T>C p.S375P | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54382278; called by muse, mutect2, varscan2
- GRM3 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100862447, COSV64467774; called by muse, mutect2, varscan2
- GSS | c.938G>A p.R313K | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.061); catalogued as COSV53628338; called by muse, mutect2
- GTF3C2 | c.1884C>A p.F628L | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.992); catalogued as COSV53128191, COSV53128786; called by muse, mutect2
- GYS1 | c.1284G>A p.M428I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV54405387; called by muse, mutect2, varscan2
- ICAM1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.96); catalogued as rs1307423569, COSV99321167; called by muse, mutect2
- IGHV3-20 | c.162C>G p.S54R | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.015); catalogued as rs113201117; called by muse, mutect2, varscan2
- IL16 | c.1029C>G p.I343M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV57267044, COSV57268136; called by muse, mutect2, varscan2
- IQCG | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54566247, COSV99502690; called by muse, mutect2
- KCNJ14 | c.1136C>A p.S379Y | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.27); catalogued as COSV60738959; called by muse, mutect2, varscan2
- KDM2A | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67083942; called by mutect2, varscan2
- KIF2B | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99276285; called by muse, mutect2, varscan2
- KIT | c.1435G>C p.D479H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV55421465; called by muse, mutect2, varscan2
- KLHL24 | c.1112G>C p.R371T | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.356); catalogued as COSV54428833; called by muse, mutect2, varscan2
- KLHL36 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.534); catalogued as COSV50723968; called by muse, mutect2, varscan2
- KMT2A | c.9830C>T p.S3277L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV63292505; called by muse, mutect2, varscan2
- KRT39 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as COSV62918035; called by muse, mutect2
- KRTAP24-1 | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 24/83 reads (29%) | catalogued as rs769750860, COSV61089510; called by muse, mutect2, varscan2
- LACTB | c.1131C>A p.Y377* | Nonsense Mutation (SNP) | VAF 4/56 reads (7%) | catalogued as COSV99979077; called by muse, mutect2
- LAMA1 | c.1630G>C p.D544H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV67535679, COSV67544429; called by muse, mutect2, varscan2
- LAT2 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs782169191, COSV51922678; called by muse, mutect2
- LONP2 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53526253; called by muse, varscan2
- LRP1B | c.9553A>T p.N3185Y | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV67274925; called by muse, mutect2, varscan2
- LRPPRC | c.3202G>A p.E1068K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV53243326; called by muse, mutect2, varscan2
- LRRK2 | c.1075T>C p.W359R | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV54170526; called by muse, mutect2, varscan2
- LSS | c.575G>A p.W192* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as rs1187570777, COSV100711064; called by muse, mutect2, varscan2
- MACC1 | c.2396A>G p.Y799C | Missense Mutation (SNP) | VAF 203/288 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV60546431; called by muse, mutect2, varscan2
- MACF1 | c.1615C>A p.P539T | Missense Mutation (SNP) | VAF 24/172 reads (14%) | catalogued as COSV58402243; called by muse, mutect2, varscan2
- MAGEB6 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770179071, COSV66873076; called by muse, mutect2, varscan2
- MAGEC1 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1368273505, COSV53568938; called by muse, mutect2, varscan2
- MAGEC1 | c.3017T>C p.I1006T | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV53581691; called by muse, mutect2, varscan2
- MAGEC3 | c.1660A>G p.S554G | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.073); catalogued as COSV68924327; called by muse, mutect2, varscan2
- MAN1A2 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV62981693; called by muse, mutect2, varscan2
- MAP6 | c.2335C>G p.L779V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.243); catalogued as COSV59077910; called by muse, mutect2
- MARCHF4 | c.999C>A p.N333K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.147); catalogued as rs374432723, COSV56108582; called by muse, mutect2, varscan2
- MDM1 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100292075; called by muse, mutect2
- MED17 | c.1161G>C p.L387F | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV52603149; called by muse, mutect2
- METTL2A | c.975C>A p.F325L | Missense Mutation (SNP) | VAF 342/838 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100274078, COSV61046092; called by muse, varscan2
- METTL3 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52971301; called by muse, mutect2
- MFAP1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.137); catalogued as rs756604625, COSV51041295; called by muse, varscan2
- MKI67 | c.519C>G p.D173E | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV64076959; called by muse, mutect2
- MKI67 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV64076964; called by muse, mutect2
- MLEC | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as COSV57330368; called by muse, mutect2, varscan2
- MLYCD | c.704G>A p.R235K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs766512025, COSV52306710; called by muse, mutect2, varscan2
- MMP8 | c.1294C>A p.H432N | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV52634310; called by muse, mutect2, varscan2
- MPG | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.078); catalogued as COSV54739553; called by muse, mutect2
- MRC1 | c.3793C>T p.R1265* | Nonsense Mutation (SNP) | VAF 37/348 reads (11%) | catalogued as rs1213618358; called by muse, mutect2, varscan2
- MS4A10 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as COSV57633934; called by muse, mutect2, varscan2
- MTMR4 | c.3281C>A p.S1094* | Nonsense Mutation (SNP) | VAF 9/112 reads (8%) | catalogued as COSV100051462; called by muse, mutect2
- MUC16 | c.39256C>T p.H13086Y | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs770063631, COSV66695589, COSV66696469; called by muse, mutect2, varscan2
- MUC16 | c.21502G>T p.D7168Y | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.41); catalogued as COSV67464691, COSV67494152; called by muse, mutect2
- MYH4 | c.4645G>C p.E1549Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759247513, COSV55126216; called by muse, mutect2, varscan2
- MYH7 | c.5218G>A p.E1740K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62517682; called by muse, mutect2, varscan2
- MYLK2 | c.1222A>G p.K408E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV65659971; called by muse, mutect2, varscan2
- NCAN | c.2052G>C p.L684F | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.055); catalogued as COSV53053382; called by muse, mutect2, varscan2
- NCDN | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.232); catalogued as COSV100357748, COSV57850664; called by muse, mutect2, varscan2
- NCKAP1L | c.2806C>G p.L936V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV53203494, COSV53212322; called by muse, mutect2, varscan2
- NECTIN4 | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.131); catalogued as COSV63514018; called by muse, mutect2, varscan2
- NEDD9 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.391); catalogued as COSV65223249; called by muse, mutect2
- NEUROD1 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54551146; called by muse, mutect2, varscan2
- NFIA | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV64544143; called by muse, mutect2, varscan2
- NINL | c.3556G>T p.E1186* | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | catalogued as COSV99626390; called by muse, mutect2
- NIT1 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as COSV63502721; called by muse, mutect2, varscan2
- NRXN1 | c.1405G>T p.V469L | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58493554; called by muse, mutect2, varscan2
- NSMAF | c.1201T>C p.Y401H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50701027; called by muse, mutect2, varscan2
- NT5DC2 | c.1501G>C p.D501H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.22); catalogued as COSV58743049; called by muse, mutect2
- NUAK1 | c.1215C>G p.S405R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV54608283; called by muse, mutect2, varscan2
- NUMB | c.238G>A p.G80R (on ENST00000355058; = p.G69R on NM_003744.5) | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as rs1275697057, COSV61832241; called by muse, mutect2, varscan2
- NUP107 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV57494724, COSV57498085; called by muse, mutect2, varscan2
- NUP188 | c.1157C>G p.S386C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.873); catalogued as COSV65364897; called by muse, mutect2, varscan2
- ODC1 | c.908C>G p.S303C | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV52173551, COSV99301282; called by muse, mutect2
- OR10H4 | c.232A>G p.I78V | Missense Mutation (SNP) | VAF 35/267 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV59063025; called by muse, mutect2, varscan2
- OR2T1 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63542887; called by muse, mutect2
- OR56A3 | c.59G>A p.C20Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs753416876, COSV61570048; called by muse, mutect2, varscan2
- OR5AS1 | c.22A>G p.M8V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV57983242; called by muse, mutect2, varscan2
- OR6C74 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59605695, COSV59606861; called by muse, mutect2, varscan2
- OR6K3 | c.418G>A p.V140I (on ENST00000368146; = p.V124I on NM_001005327.2) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs773825307, COSV63746516; called by muse, mutect2, varscan2
- OSTM1 | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.061); catalogued as COSV51971841; called by muse, mutect2, varscan2
- PABPC3 | c.49del p.D17Tfs*6 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as rs765811765; called by mutect2, pindel, varscan2
- PADI4 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV64925087; called by muse, mutect2, varscan2
- PCDH9 | c.2719C>G p.P907A | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.557); catalogued as COSV60582037, COSV60590483; called by muse, mutect2, varscan2
- PCDHA12 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV56545809; called by muse, mutect2, varscan2
- PCDHA2 | c.2066C>G p.S689* | Nonsense Mutation (SNP) | VAF 20/109 reads (18%) | catalogued as COSV100974162; called by muse, mutect2, varscan2
- PCDHB5 | c.1495C>T p.L499F | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV50670932; called by muse, mutect2
- PCNT | c.3359G>A p.R1120H | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.96); PolyPhen benign (0.013); catalogued as rs777563319, COSV64033045; called by muse, mutect2, varscan2
- PDCD7 | c.1038G>C p.E346D | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV52601459, COSV99200136; called by muse, mutect2
- PDE1C | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as rs768497187, COSV58524849; called by muse, mutect2
- PDE8B | c.685C>G p.L229V | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53745533; called by muse, mutect2
- PEX12 | c.367C>T p.L123F | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV56778949; called by muse, mutect2, varscan2
- PGPEP1 | c.472T>G p.Y158D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV53253019; called by muse, mutect2, varscan2
- PI4KA | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV55423110; called by muse, mutect2, varscan2
- PLA2R1 | c.2177T>A p.F726Y | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99323621; called by muse, mutect2
- PLCB4 | c.3291C>G p.I1097M | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as COSV53816200; called by muse, mutect2
- PLEC | c.9469C>T p.L3157F (on ENST00000322810 / NM_201380.4; = p.L3047F on NM_000445.5) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV59651523; called by muse, mutect2, varscan2
- PLEKHA5 | c.2548C>T p.P850S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV54712560; called by muse, mutect2, varscan2
- PLK1 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV55624303; called by muse, mutect2
- PRAMEF1 | c.339G>C p.W113C | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60018375; called by muse, mutect2, varscan2
- PRR16 | c.384G>T p.R128S (on ENST00000407149 / NM_001300783.2; = p.R105S on NM_016644.2) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV65406112; called by muse, mutect2, varscan2
- PSMB11 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as rs1016283829, COSV101273645, COSV68430469; called by muse, mutect2
- PSMB5 | c.734G>C p.R245P | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); catalogued as COSV57801314; called by muse, mutect2, varscan2
- PTBP2 | c.821A>G p.N274S (on ENST00000426398 / NM_001300986.2; = p.N266S on NM_021190.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.751); catalogued as rs771286928, COSV64626538; called by muse, mutect2, varscan2
- PTPRC | c.1097A>T p.K366M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV61420552; called by muse, mutect2, varscan2
- PTPRG | c.3314C>A p.T1105N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM142564, COSV99877006; called by muse, mutect2
- PUS7 | c.960G>C p.L320F | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV62678500; called by muse, mutect2
- PYGB | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99405472; called by muse, mutect2
- QSOX2 | c.1912G>A p.G638R | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV62395319; called by muse, mutect2, varscan2
- RABL2B | c.651G>C p.E217D | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.025); catalogued as COSV61483915, COSV61483940; called by muse, mutect2, varscan2
- RAPGEF4 | c.2028C>A p.C676* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV51418624, COSV99911731; called by muse, mutect2, varscan2
- RASAL1 | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 20/390 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55659779; called by muse, mutect2
- RB1CC1 | c.2468G>C p.R823T | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV50274722; called by muse, mutect2
- RBM47 | c.1762G>A p.D588N (on ENST00000295971 / NM_001098634.2; = p.D519N on NM_019027.4) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as rs769388482, COSV55943459; called by muse, mutect2, varscan2
- RFX7 | c.1110G>A p.M370I (on ENST00000559447 / NM_001368074.1; = p.M467I on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV57968798; called by muse, mutect2, varscan2
- RINT1 | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777291719, COSV57560745; called by muse, mutect2, varscan2
- RNF103 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52895769; called by muse, mutect2
- RNF13 | c.802G>C p.D268H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53524986; called by muse, mutect2, varscan2
- ROBO1 | c.3191T>G p.V1064G | Missense Mutation (SNP) | VAF 5/109 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV71398611; called by muse, mutect2
- RPS20 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.2); catalogued as COSV50537201; called by muse, mutect2, varscan2
- SACS | c.8416A>G p.M2806V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as rs941542740, COSV66546770; called by muse, mutect2, varscan2
- SATB1 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV58672726; called by muse, mutect2
- SCN11A | c.2034C>G p.F678L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs981721148, COSV56578469; called by muse, mutect2, varscan2
- SCYL3 | c.956-1G>C p.X319_splice | Splice Site (SNP) | VAF 9/126 reads (7%) | catalogued as rs1197100965, COSV100884324; called by muse, mutect2
- SEMA3D | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52404646; called by muse, mutect2, varscan2
- SETX | c.1195C>G p.Q399E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV56394619; called by muse, mutect2, varscan2
- SFMBT2 | c.1117A>G p.K373E | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.982); catalogued as COSV62816684; called by muse, mutect2, varscan2
- SLC12A1 | c.2463C>G p.I821M | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV101118461; called by muse, mutect2
- SLC37A1 | c.573G>C p.L191F | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.261); catalogued as COSV61404702; called by muse, mutect2
- SLC9A4 | c.1474G>C p.E492Q | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.334); catalogued as COSV54833540, COSV54839289; called by muse, mutect2, varscan2
- SMC2 | c.1339G>C p.D447H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV53964570; called by muse, mutect2, varscan2
- SPATA5 | c.2653C>G p.Q885E | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as rs1387497334, COSV56777324, COSV56783516; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPDYE1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs761983197, COSV51671227; called by muse, mutect2, varscan2
- SPECC1 | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV54962025; called by muse, mutect2, varscan2
- SPEN | c.3382G>A p.D1128N | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV101005632; called by muse, mutect2
- STK4 | c.405G>T p.K135N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.571); catalogued as COSV65672085; called by muse, mutect2
- STRN4 | c.701C>G p.S234W | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV54418830, COSV54421158; called by muse, mutect2, varscan2
- TANC1 | c.2382G>T p.R794S | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV55097039; called by muse, mutect2, varscan2
- TARDBP | c.332T>G p.L111R | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53571373; called by muse, mutect2
- TCEA2 | c.675G>C p.E225D | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100180904; called by muse, mutect2
- TENM1 | c.1820G>T p.C607F | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64443350; called by muse, mutect2, varscan2
- TEX2 | c.2512G>C p.E838Q (on ENST00000583097 / NM_001288733.2; = p.E845Q on NM_018469.5) | Missense Mutation (SNP) | VAF 15/396 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51985588; called by muse, mutect2
- TFAP2A | c.1035G>C p.Q345H (on ENST00000482890; = p.Q337H on NM_001032280.3) | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60237624; called by muse, mutect2
- TGFBRAP1 | c.559C>G p.Q187E | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV51516339; called by muse, mutect2, varscan2
- TGM5 | c.460G>A p.E154K (on ENST00000220420 / NM_201631.4; = p.E72K on NM_004245.4) | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV55012277; called by muse, mutect2, varscan2
- TIE1 | c.3127C>A p.L1043I | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65251407; called by muse, mutect2, varscan2
- TIPARP | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55815702; called by muse, mutect2
- TMC6 | c.1656C>A p.F552L | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV59811668; called by muse, mutect2, varscan2
- TMEM132B | c.1969A>G p.I657V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.043); catalogued as COSV100171052; called by muse, varscan2
- TMPRSS7 | c.1310+1G>A p.X437_splice (on ENST00000452346; = p.X311_splice on NM_001042575.2) | Splice Site (SNP) | VAF 4/16 reads (25%) | catalogued as rs746221604, COSV69982608; called by muse, varscan2
- TNKS2 | c.1300C>G p.Q434E | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); catalogued as COSV65417008; called by muse, mutect2, varscan2
- TNN | c.344T>A p.L115Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53435604; called by muse, mutect2, varscan2
- TPP2 | c.2581G>C p.D861H | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101060460, COSV65752177; called by muse, mutect2
- TRAM1 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51600567; called by muse, mutect2
- TREH | c.1529C>A p.S510* | Nonsense Mutation (SNP) | VAF 25/137 reads (18%) | catalogued as COSV99874814; called by muse, mutect2, varscan2
- TTC3 | c.3481C>A p.R1161S | Missense Mutation (SNP) | VAF 20/285 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV61288547, COSV61296257; called by muse, mutect2
- TTN | c.100076A>T p.E33359V (on ENST00000591111; = p.E25935V on NM_003319.4) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | PolyPhen benign (0.436); catalogued as COSV60348496; called by muse, mutect2, varscan2
- TTN | c.77928G>C p.W25976C (on ENST00000591111; = p.W18552C on NM_003319.4) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | PolyPhen probably damaging (0.999); catalogued as COSV60010055, COSV60348537; called by muse, mutect2
- TTN | c.14902G>A p.A4968T (on ENST00000591111; = p.A4041T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/114 reads (25%) | PolyPhen benign (0); catalogued as COSV100615955, COSV60113963; called by muse, mutect2, varscan2
- UBL4A | c.405C>G p.I135M | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54835507, COSV54837554; called by muse, mutect2, varscan2
- UBL4A | c.194C>G p.S65C | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54837558; called by muse, mutect2
- UBXN4 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV55638132, COSV99067447; called by muse, mutect2, varscan2
- UGT2A3 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV52362125; called by muse, mutect2, varscan2
- USH2A | c.8627G>T p.W2876L | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56436418; called by muse, mutect2, varscan2
- USP18 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV53174482; called by muse, mutect2, varscan2
- USP53 | c.1843A>T p.N615Y | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV56797658; called by mutect2, varscan2
- VPS13C | c.7250C>G p.S2417C (on ENST00000644861 / NM_020821.3; = p.S2374C on NM_017684.5) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.706); catalogued as COSV51424677; called by muse, mutect2, varscan2
- VPS72 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.326); catalogued as COSV63167086, COSV63168224; called by muse, mutect2
- WAC | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV61569803; called by muse, mutect2, varscan2
- WASHC4 | c.1326+1G>T p.X442_splice | Splice Site (SNP) | VAF 15/85 reads (18%) | catalogued as COSV59892369; called by muse, mutect2, varscan2
- WDR59 | c.2453G>A p.W818* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as COSV100049746; called by muse, mutect2, varscan2
- WNK1 | c.3145G>C p.E1049Q (on ENST00000315939 / NM_018979.4; = p.E802Q on NM_014823.3) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.433); catalogued as COSV60045119; called by muse, mutect2, varscan2
- ZEB2 | c.2782C>A p.Q928K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.9); catalogued as COSV57966259; called by muse, mutect2, varscan2
- ZFR | c.586C>G p.Q196E | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.68); catalogued as COSV54057835; called by muse, mutect2, varscan2
- ZIC1 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV99292473; called by muse, mutect2
- ZMYM4 | c.4555A>G p.T1519A | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.11); catalogued as rs1383973627, COSV58917204; called by muse, mutect2, varscan2
- ZMYM6 | c.1306C>G p.L436V | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.232); catalogued as COSV64122642; called by muse, mutect2, varscan2
- ZNF225 | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV53473161; called by muse, mutect2, varscan2
- ZNF287 | c.2229G>C p.Q743H | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.978); catalogued as COSV67689115; called by muse, mutect2, varscan2
- ZNF407 | c.3086C>G p.S1029C | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1208094184, COSV55270062; called by muse, mutect2
- ZNF423 | c.646C>A p.H216N (on ENST00000563137 / NM_001379286.1; = p.H208N on NM_015069.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV52204693; called by muse, varscan2
- ZNF468 | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767066715, COSV54697037; called by muse, mutect2, varscan2
- ZNF511 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.071); catalogued as COSV62920714; called by muse, mutect2, varscan2
- ZNF536 | c.3866C>T p.S1289F | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as COSV100834591, COSV62834057; called by muse, mutect2
- ZNF613 | c.1679G>T p.R560L (on ENST00000293471 / NM_001031721.4; = p.R524L on NM_024840.4) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV53270849, COSV53273971; called by muse, mutect2, varscan2
- ZNF625 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.596); catalogued as rs1213545689, COSV63242783, COSV63243273; called by muse, mutect2
- ZNF770 | c.89A>G p.N30S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.55); catalogued as COSV62545071; called by muse, mutect2, varscan2
- C1GALT1C1L | c.590G>A p.R197K | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.97); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- FBXL16 | c.1279C>A p.L427M | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- MAN2B1 | c.2300A>T p.Q767L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0.049); called by muse, mutect2
- PCDH7 | c.2415G>C p.R805S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PNMA8A | c.269del p.G90Vfs*18 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- PSMB3 | c.68C>A p.A23D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC9C1 | c.31A>G p.S11G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- SPATA13 | c.1279_1295del p.K427Qfs*35 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel
- THAP11 | c.727G>C p.D243H | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TMEM236 | c.116G>T p.R39M | Missense Mutation (SNP) | VAF 66/466 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UHRF1BP1L | c.1535G>C p.G512A | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.354); called by muse, mutect2
- ZP4 | c.97del p.H33Tfs*11 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel, varscan2
- AAR2 | c.832C>T p.L278= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV57924980; called by muse, mutect2, varscan2
- ABCG4 | c.1392C>G p.L464= | Silent (SNP) | VAF 16/151 reads (11%) | called by muse, mutect2
- ABLIM3 | c.1251G>C p.V417= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV58648690; called by muse, mutect2, varscan2
- AC139530.2 | c.402G>C p.L134= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV100230784; called by muse, mutect2
- ACTR1A | c.711G>A p.E237= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as COSV64024217; called by muse, mutect2, varscan2
- ACTRT2 | c.525G>A p.L175= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs1394232533, COSV65760534; called by muse, mutect2, varscan2
- ALAS1 | c.1413C>T p.F471= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV59627395, COSV59628469; called by muse, mutect2, varscan2
- AP3S2 | c.531C>T p.I177= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as rs764344985, COSV60519917; called by muse, mutect2
- AP5B1 | c.795G>A p.R265= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV57504306; called by muse, mutect2
- APC | c.8385A>G p.A2795= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV57382502; called by muse, mutect2, varscan2
- ATP1A2 | c.879C>T p.I293= | Silent (SNP) | VAF 8/103 reads (8%) | catalogued as COSV63405911; called by muse, mutect2
- BPIFB2 | c.207C>A p.I69= | Silent (SNP) | VAF 14/193 reads (7%) | catalogued as COSV50070803; called by muse, mutect2
- C3 | c.1896G>A p.G632= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV55581411; called by muse, mutect2, varscan2
- CAMK2B | c.351C>T p.I117= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99323579; called by muse, mutect2
- CCNB3 | c.3171A>T p.P1057= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV52079687; called by muse, mutect2, varscan2
- CDC25B | c.1677C>G p.L559= (on ENST00000245960 / NM_021873.3; = p.L545= on NM_004358.4) | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs755324000, COSV55659620; called by muse, mutect2, varscan2
- CENPL | c.885C>T p.F295= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV61891659, COSV61893006; called by muse, mutect2, varscan2
- CFH | c.2865T>A p.V955= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV66413530; called by muse, mutect2
- CHD6 | c.3072G>A p.Q1024= | Silent (SNP) | VAF 13/142 reads (9%) | catalogued as COSV58562434; called by muse, mutect2
- CRACR2A | c.852G>A p.Q284= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV52918461; called by muse, mutect2, varscan2
- CXCL1 | c.150G>A p.Q50= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs780671066, COSV67611887; called by muse, mutect2, varscan2
- CYFIP1 | c.522G>A p.L174= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs767926977; called by muse, mutect2, varscan2
- DSEL | c.153G>A p.Q51= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV59494774; called by muse, mutect2
- ECD | c.996C>G p.L332= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV65901261; called by muse, mutect2, varscan2
- EED | c.33G>C p.A11= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV54558387, COSV54558538; called by muse, mutect2, varscan2
- EIF1 | c.126G>A p.K42= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV60423002; called by muse, mutect2, varscan2
- ELANE | c.780G>A p.P260= | Silent (SNP) | VAF 10/182 reads (5%) | catalogued as rs201284307, COSV55049602; called by muse, mutect2
- EPHA3 | c.501G>A p.E167= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV60727478, COSV60733065; called by muse, mutect2, varscan2
- ERMAP | c.1320G>A p.V440= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV60276048; called by muse, mutect2, varscan2
- EXT2 | c.1623C>T p.I541= (on ENST00000343631; = p.I574= on NM_000401.3) | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV59155237; called by muse, mutect2, varscan2
- F2 | c.1407G>A p.K469= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV61315277, COSV61317694; called by muse, mutect2, varscan2
- FBXL14 | c.936C>T p.L312= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV59337601; called by muse, mutect2, varscan2
- FBXL16 | c.1278C>T p.L426= | Silent (SNP) | VAF 2/14 reads (14%) | catalogued as COSV99556282; called by muse, mutect2
- FN3K | c.576C>G p.L192= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as rs1157678484, COSV100333389; called by muse, mutect2
- GRIA2 | c.1821G>A p.Q607= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV52406246; called by muse, mutect2, varscan2
- GRIK4 | c.6C>T p.P2= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as rs1393896611, COSV70807231; called by muse, mutect2, varscan2
- HHIPL1 | c.1017C>G p.P339= | Silent (SNP) | VAF 27/242 reads (11%) | catalogued as COSV58093560; called by muse, mutect2, varscan2
- HK2 | c.684C>T p.L228= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs747917476, COSV51878833; called by muse, mutect2
- KIF16B | c.3072C>A p.T1024= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV61715151; called by muse, mutect2, varscan2
- LRRC37B | c.2559C>G p.L853= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV100496350, COSV100496542; called by muse, mutect2
- MAGEC1 | c.252G>A p.Q84= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV53581668; called by muse, mutect2, varscan2
- MAN2A2 | c.3033C>A p.L1011= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV64639909; called by muse, mutect2, varscan2
- MBD5 | c.1221C>G p.L407= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as COSV68695857, COSV68698950; called by muse, varscan2
- MGAT5 | c.327C>T p.V109= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV56101241; called by muse, mutect2, varscan2
- MIGA1 | c.1824G>A p.L608= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100889818; called by muse, mutect2
- NFX1 | c.2499G>A p.G833= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV100582084; called by muse, mutect2
- NOL12 | c.363C>A p.L121= | Silent (SNP) | VAF 12/131 reads (9%) | catalogued as COSV63031780; called by muse, mutect2
- NUP205 | c.5101C>T p.L1701= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as rs1225368291, COSV53666044; called by muse, mutect2, varscan2
- OLFM1 | c.1083G>A p.E361= (on ENST00000371793 / NM_001282611.2; = p.E343= on NM_014279.5) | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV53282345; called by muse, mutect2, varscan2
- OR10H1 | c.21C>T p.S7= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV58473083; called by muse, mutect2
- OR4A15 | c.159G>A p.L53= | Silent (SNP) | VAF 64/132 reads (48%) | catalogued as COSV100124302, COSV59037706; called by muse, mutect2, varscan2
- OR52I1 | c.666T>C p.Y222= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as COSV56170076; called by muse, mutect2, varscan2
- OR6M1 | c.600T>A p.S200= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV58434894; called by muse, mutect2, varscan2
- OR8B8 | c.678C>T p.F226= | Silent (SNP) | VAF 57/126 reads (45%) | catalogued as COSV60145758; called by muse, mutect2, varscan2
- PADI1 | c.633G>A p.V211= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV64938522, COSV64939303; called by muse, mutect2, varscan2
- PAGE3 | c.292C>T p.L98= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV66587306; called by muse, mutect2, varscan2
- PCDHA7 | c.2061A>T p.A687= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV65340486; called by muse, mutect2, varscan2
- PCDHB5 | c.1497C>A p.L499= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV50648133, COSV50670990; called by muse, mutect2
- PCDHB6 | c.1854C>T p.H618= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV50711920, COSV99171417; called by muse, mutect2, varscan2
- PCDHGB4 | c.981G>A p.A327= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs370432555; called by mutect2, varscan2
- PIK3AP1 | c.462G>A p.E154= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV59537421; called by muse, mutect2, varscan2
- PLAG1 | c.1305A>G p.L435= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs780686291, COSV57615181; called by muse, mutect2, varscan2
- POLR2A | c.3585C>G p.V1195= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs1321731315; called by muse, mutect2, varscan2
- PSG3 | c.660G>A p.R220= | Silent (SNP) | VAF 32/354 reads (9%) | catalogued as COSV59506814; called by muse, mutect2
- ROBO2 | c.2100C>T p.V700= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs781426684, COSV59938868; called by muse, mutect2, varscan2
- RPS6KB2 | c.630G>C p.L210= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100412393; called by muse, mutect2
- RSKR | c.447G>A p.V149= | Silent (SNP) | VAF 11/141 reads (8%) | catalogued as COSV56383970; called by muse, mutect2
- RYR1 | c.10380C>G p.V3460= | Silent (SNP) | VAF 20/440 reads (5%) | catalogued as COSV62101909, COSV62110701; called by muse, mutect2
- RYR2 | c.11193C>T p.L3731= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs766861176, COSV63713570; called by muse, mutect2, varscan2
- SLC18A2 | c.780C>G p.L260= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV53691328, COSV53693565; called by muse, mutect2
- SLC2A13 | c.1398C>T p.S466= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV55128357; called by muse, varscan2
- SLITRK3 | c.2448G>A p.K816= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV53845778, COSV53849959; called by muse, mutect2, varscan2
- SPIRE2 | c.1209G>T p.P403= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV65557666; called by muse, mutect2, varscan2
- STAG1 | c.255C>G p.V85= | Silent (SNP) | VAF 13/218 reads (6%) | catalogued as rs750503206, COSV52623989, COSV99365432; called by muse, mutect2
- STYXL2 | c.66G>A p.V22= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as rs1194160924, COSV99609716; called by muse, mutect2
- TEAD4 | c.123C>A p.G41= | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as COSV63282489; called by muse, mutect2, varscan2
- TMEM150B | c.162C>A p.I54= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100442477; called by muse, mutect2
- TMEM150B | c.105C>A p.L35= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV58594038; called by muse, varscan2
- TMEM150C | c.405G>A p.L135= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV71389539; called by muse, mutect2
- TMEM270 | c.39G>A p.G13= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs1311128032, COSV57639731; called by muse, mutect2, varscan2
- TMEM270 | c.201A>G p.G67= | Silent (SNP) | VAF 10/164 reads (6%) | catalogued as COSV100260412; called by muse, mutect2
- TRIM25 | c.1032C>G p.L344= | Silent (SNP) | VAF 30/325 reads (9%) | catalogued as COSV57545969; called by muse, mutect2
- TRPM8 | c.2349G>C p.V783= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as rs1166977822, COSV61224231; called by muse, mutect2
- TTC12 | c.1131C>T p.I377= | Silent (SNP) | VAF 47/105 reads (45%) | catalogued as rs1428907201, COSV59100162; called by muse, mutect2, varscan2
- TTN | c.102573C>T p.F34191= (on ENST00000591111; = p.F26767= on NM_003319.4) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV60348456; called by muse, mutect2, varscan2
- TTN | c.19650C>T p.A6550= (on ENST00000591111; = p.A5623= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs374731328, COSV60281947; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBC | c.1848G>A p.L616= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as COSV100299145; called by muse, varscan2
- VDR | c.54G>C p.R18= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV57470615; called by muse, mutect2, varscan2
- ZDHHC7 | c.726C>T p.I242= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as rs769339090, COSV58214024; called by muse, mutect2, varscan2
- ZFYVE28 | c.2589G>A p.V863= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV52117477; called by muse, mutect2, varscan2
- ZNF613 | c.891C>T p.F297= (on ENST00000293471 / NM_001031721.4; = p.F261= on NM_024840.4) | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV53273958; called by muse, mutect2
- ZNF816-ZNF321P | c.396C>T p.I132= | Silent (SNP) | VAF 46/226 reads (20%) | catalogued as COSV100008450, COSV58350028; called by muse, mutect2, varscan2
- CCDC62 | c.*87G>A | 3'UTR (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99457742; called by muse, mutect2, varscan2
- CD300LD | chr17:74592642 C>T | 5'Flank (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- CSH1 | c.456+28C>A | Intron (SNP) | VAF 16/138 reads (12%) | catalogued as COSV60243018; called by muse, mutect2, varscan2
- ELMOD1 | c.-86+977G>C | Intron (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99760443; called by muse, mutect2, varscan2
- PREX2 | c.2716-2851C>A | Intron (SNP) | VAF 4/67 reads (6%) | catalogued as COSV55777681, COSV99910135; called by muse, mutect2
- RARA | c.179-5479C>T | Intron (SNP) | VAF 25/249 reads (10%) | catalogued as COSV54197004; called by muse, mutect2, varscan2
- SYTL2 | c.1459+1493G>C | Intron (SNP) | VAF 7/57 reads (12%) | catalogued as COSV100313829, COSV60363694; called by muse, mutect2, varscan2
- XIRP2 | c.*1402C>T | 3'UTR (SNP) | VAF 9/71 reads (13%) | catalogued as COSV54734194; called by muse, mutect2, varscan2
- ZNF677 | c.-2G>C | 5'UTR (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100448200; called by muse, mutect2, varscan2
